Gene-level copy-number profile of tumor specimen ALCH-B1KX-TTP1-A from ALCHEMIST case ALCH-B1KX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.6 years (21,047 days).
Specimen ALCH-B1KX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file beb4234d-b81d-4807-8fa9-4f4df62f7c52.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1KX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,728 have no estimate.
https://portal.gdc.cancer.gov/files/51b29869-2097-4129-81a2-4fa7440d8a42

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 212; copy number 1: 3,801; copy number 2: 54,589; copy number 3: 206; copy number 4: 76; copy number 5: 11.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:218,274,197–218,292,586, 2 genes (within-gene range 0–2): TMBIM1, MIR6513.
- chr2:232,520,388–232,548,115, 3 genes (within-gene range 0–2): PRSS56, CHRND, CHRNG.
- chr6:34,537,802–34,556,333, 1 gene: SPDEF.
- chr6:110,958,706–110,967,890, 1 gene: GTF3C6.
- chr9:124,853,417–124,857,890, 1 gene (within-gene range 0–2): WDR38.
- chr9:130,651,799–130,682,986, 2 genes: AL359092.2, PRDM12.
- chr11:73,376,399–73,397,474, 2 genes (within-gene range 0–2): RELT, AP000763.4.
- chr11:113,405,321–113,412,117, 1 gene (within-gene range 0–2): AP002840.1.
- chr15:75,674,322–75,712,848, 3 genes: CSPG4, AC105020.4, AC105020.1.
- chr15:77,894,684–77,904,674, 1 gene: CSPG4P13.
- chr15:78,759,206–78,811,464, 1 gene (within-gene range 0–2): ADAMTS7.
- chr16:1,512,979–1,514,675, 1 gene (within-gene range 0–2): AL031705.1.
- chr16:14,303,967–14,304,049, 1 gene (within-gene range 0–2): MIR193B.
- chr16:28,862,166–28,863,340, 1 gene (within-gene range 0–2): AC133550.3.
- chr16:28,878,957–28,881,607, 2 genes (within-gene range 0–2): ATP2A1-AS1, AC133550.1.
- chr17:46,259,551–46,260,606, 1 gene: AC005829.2.
- chr19:10,701,430–10,713,437, 1 gene: QTRT1.
- chr19:41,425,359–41,428,730, 2 genes: AC011462.2, B3GNT8.
- chr20:62,513,909–62,516,096, 1 gene: AL499627.1.
- chr22:29,191,697–29,191,808, 1 gene (within-gene range 0–2): RNU6-1219P.
- chr22:30,356,635–30,378,658, 1 gene (within-gene range 0–2): CCDC157.
- chr22:43,166,622–43,187,134, 1 gene: TTLL12.
- chr22:43,212,674–43,239,010, 2 genes (within-gene range 0–2): SCUBE1-AS2, Z82214.1.
- chr22:46,091,044–46,091,126, 1 gene (within-gene range 0–2): MIR3619.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:8,839,700–8,898,052, 1 gene, copy number 5: LINC02199.
- chr5:25,404,733–25,445,925, 2 genes, copy number 5: AC022140.1, AC022140.2.
- chr8:142,834,138–142,834,940, 1 gene, copy number 5 (within-gene range 2–5): AC083841.3.
- chr9:12,134–89,850, 7 genes, copy number 5: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1.

Autosomal genes at a single copy (total copy number 1): 1,232. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
